Somatic mutation profile of tumor specimen 0DJHH3 from CCDI case PBBWER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,232 days).
Specimen 0DJHH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d076710-0ce3-4e6d-8cf5-757fde90fa0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8235efc8-a1bd-4671-aa69-4df87b52b51e

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 3, Nonsense Mutation 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 154/664 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA13 | c.10481A>G p.Y3494C | Missense Mutation (SNP) | VAF 465/985 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775183590; called by muse, varscan2
- CD300E | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 174/601 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as rs772510010; called by muse, varscan2
- CFAP44 | c.5257C>T p.R1753* | Nonsense Mutation (SNP) | VAF 154/763 reads (20%) | catalogued as rs1303765259, COSV100385568, COSV57663362; called by muse, varscan2
- HELZ2 | c.5557G>A p.A1853T (on ENST00000467148 / NM_001037335.2; = p.A1284T on NM_033405.3) | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs576323272; called by muse, varscan2
- L3MBTL1 | c.790G>T p.E264* (on ENST00000418998 / NM_001377303.1; = p.E174* on NM_015478.7) | Nonsense Mutation (SNP) | VAF 53/302 reads (18%) | catalogued as COSV100917154; called by muse, varscan2
- NRBP1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 141/929 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV51993837; called by muse, varscan2
- PLEKHG6 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.169); catalogued as rs942386258; called by muse, varscan2
- PRAMEF9 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1393464940; called by muse, varscan2
- TLR10 | c.1943T>A p.V648E | Missense Mutation (SNP) | VAF 82/551 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV58301951; called by muse, varscan2
- XKR5 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as rs570446413; called by muse, varscan2
- ZNF792 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 116/508 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200960200, COSV68692840; called by muse, varscan2
- ABCC12 | c.3675G>T p.M1225I | Missense Mutation (SNP) | VAF 105/570 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- EFNA4 | c.344T>A p.F115Y | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, varscan2
- ELP2 | c.1259G>T p.R420I | Missense Mutation (SNP) | VAF 122/761 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, varscan2
- ERMARD | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 102/821 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FBF1 | c.968C>G p.P323R (on ENST00000586717; = p.P337R on NM_001319193.1) | Missense Mutation (SNP) | VAF 154/636 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.424); called by muse, varscan2
- KCTD2 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LPXN | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 106/528 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, varscan2
- LY75 | c.2743G>T p.D915Y | Missense Mutation (SNP) | VAF 190/838 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- TASOR | c.4383C>A p.S1461R (on ENST00000355628 / NM_001365636.2; = p.S1085R on NM_015224.3) | Missense Mutation (SNP) | VAF 166/692 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, varscan2
- TC2N | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 76/506 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- COL12A1 | c.8832G>A p.P2944= | Silent (SNP) | VAF 98/612 reads (16%) | called by muse, varscan2
- EPB42 | c.747G>A p.V249= (on ENST00000441366 / NM_001114134.2; = p.V279= on NM_000119.3) | Silent (SNP) | VAF 82/321 reads (26%) | catalogued as COSV55749480; called by muse, varscan2
- H3C6 | c.408G>C p.A136= | Silent (SNP) | VAF 70/483 reads (14%) | called by muse, varscan2
- KIAA1755 | c.813C>T p.F271= | Silent (SNP) | VAF 101/541 reads (19%) | catalogued as rs147347811; called by muse, varscan2
- LAMB3 | c.2980C>T p.L994= | Silent (SNP) | VAF 100/408 reads (25%) | called by muse, varscan2
- OR10C1 | c.267C>A p.G89= (on ENST00000622521; = p.G87= on NM_013941.3) | Silent (SNP) | VAF 116/646 reads (18%) | catalogued as COSV65822416; called by muse, varscan2
- OTUD7A | c.1809G>A p.A603= (on ENST00000307050 / NM_001382637.1; = p.A596= on NM_130901.3) | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as rs547007498, COSV61044001; called by muse, varscan2
- SLC4A5 | c.3039G>A p.P1013= | Silent (SNP) | VAF 90/528 reads (17%) | catalogued as rs754177091, COSV61024665; called by muse, varscan2
- VARS2 | c.1104C>T p.P368= | Silent (SNP) | VAF 110/771 reads (14%) | catalogued as COSV58912729; called by muse, varscan2
- ENG | c.*19G>A | 3'UTR (SNP) | VAF 31/157 reads (20%) | catalogued as rs545822507, COSV61229689; called by muse, varscan2
- FCGR2A | c.107-20C>A | Intron (SNP) | VAF 62/320 reads (19%) | called by muse, varscan2
- PAN2 | c.2078-10T>G | Intron (SNP) | VAF 36/152 reads (24%) | called by muse, varscan2
- RPS6KB1 | c.*46G>A | 3'UTR (SNP) | VAF 124/381 reads (33%) | catalogued as COSV99847549; called by muse, varscan2
- STAT5B | c.1775+22G>A | Intron (SNP) | VAF 118/928 reads (13%) | called by muse, varscan2
